Gene-level copy-number profile of tumor specimen TCGA-5M-AAT6-01A from TCGA case TCGA-5M-AAT6, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IV; Age at diagnosis: 40.7 years (14,852 days).
Specimen TCGA-5M-AAT6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.9f35a0c6-c973-44a6-803c-3dfadfb3d8fb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-5M-AAT6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3b692e30-2e99-4c94-afb9-564ce070b570

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 974; copy number 2: 55,875; copy number 3: 1,390; copy number 5: 1,569.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-5M-AAT6-01A-11D-A40O-01): tumor purity 0.25, ploidy 2.13, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:136,329,441–136,329,913, 1 gene: UBBP1.
- chr2:194,454,581–194,455,142, 1 gene: AC106883.1.
- chr4:12,639,086–12,641,009, 2 genes: ECM1P2, AC093809.1.
- chr4:14,909,961–15,002,045, 1 gene (within-gene range 0–2): CPEB2-DT.
- chr10:8,259,331–8,301,667, 2 genes: LINC00708, AL390835.1.
- chr12:40,140,926–40,142,876, 1 gene: LINC02555.
- chr12:128,052,122–128,123,103, 3 genes: AC140121.1, LINC02369, LINC02368.
- chr13:38,965,925–38,990,859, 1 gene: STOML3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,569 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:42,836,674–145,066,685, 1,569 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 917. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
